Somatic mutation profile of tumor specimen TCGA-DU-5849-01A (aliquot TCGA-DU-5849-01A-11D-1705-08) from TCGA case TCGA-DU-5849, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 48.4 years (17,663 days).
Specimen TCGA-DU-5849-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 907c228c-1f5a-4285-9260-328a6d2885c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-5849-10A (Blood Derived Normal), aliquot TCGA-DU-5849-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f267631-2a0f-49dd-bfbc-f2d7c3099594

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 7, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.455A>G p.Y152C (on ENST00000506720 / NM_001322402.2; = p.Y84C on NM_015236.6) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72268425; called by muse, mutect2, varscan2
- CACNG3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064973; called by muse, mutect2, varscan2
- CNOT1 | c.6164C>T p.T2055M | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1394701183, COSV55315252; called by muse, mutect2, varscan2
- CUBN | c.10312C>A p.H3438N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV64713793, COSV64715695; called by muse, mutect2, varscan2
- DDA1 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as COSV63289581; called by mutect2, varscan2
- DNAH5 | c.11457G>C p.V3819= | Splice Region (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54224729, COSV99455907; called by muse, mutect2
- DONSON | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1041741921, COSV51676742; called by muse, mutect2, varscan2
- EPPK1 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs376915151; called by muse, mutect2, varscan2
- GIMAP5 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57529999; called by muse, mutect2, varscan2
- HAL | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV54117867; called by muse, mutect2, varscan2
- HDHD2 | c.376A>C p.I126L | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56075938; called by muse, mutect2
- IMPG1 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as rs751273411, COSV64057744; called by muse, mutect2, varscan2
- KRTAP10-12 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782227543, COSV59962214; called by muse, mutect2, varscan2
- KY | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.04); catalogued as rs373172556; called by muse, mutect2
- NXF3 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs754238091, COSV67702972, COSV67703547; called by muse, mutect2, varscan2
- PCDH15 | c.4630A>G p.T1544A | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV64694118, COSV64733797; called by muse, mutect2
- PER1 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV57919437; called by muse, mutect2, varscan2
- PRKDC | c.8199G>T p.M2733I | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58052322; called by muse, mutect2, varscan2
- RALGAPA2 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV52489048, COSV52497640; called by muse, mutect2, varscan2
- SMC2 | c.377G>C p.R126T | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53958227; called by muse, mutect2
- SPATA31D1 | c.911T>A p.L304* | Nonsense Mutation (SNP) | VAF 60/288 reads (21%) | catalogued as COSV61195739; called by muse, mutect2, varscan2
- TICAM1 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV50229383; called by muse, mutect2, varscan2
- TPM1 | c.703-1G>A p.X235_splice | Splice Site (SNP) | VAF 16/79 reads (20%) | catalogued as COSV51261161; called by muse, mutect2, varscan2
- ZBTB20 | c.731A>G p.Y244C (on ENST00000474710 / NM_001164342.2; = p.Y171C on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61850631; called by muse, mutect2, varscan2
- ART3 | c.792C>T p.T264= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs746991811, COSV61914047; called by muse, mutect2, varscan2
- COPA | c.1860A>G p.L620= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV54102374; called by muse, mutect2, varscan2
- DNAJB7 | c.801G>A p.E267= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV53421847; called by muse, mutect2, varscan2
- GLI2 | c.156G>A p.Q52= | Silent (SNP) | VAF 12/190 reads (6%) | catalogued as COSV58041968; called by muse, mutect2
- IL12RB1 | c.375G>A p.K125= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1182042515, COSV59097151; called by muse, mutect2, varscan2
- SERPINI1 | c.414T>C p.H138= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs758630825, COSV55510801; ClinVar: likely benign; called by muse, mutect2, varscan2
- VRK2 | c.177A>G p.V59= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV60876723; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840398 C>A | 5'Flank (SNP) | VAF 25/80 reads (31%) | catalogued as COSV58335226; called by muse, mutect2, varscan2
